Somatic mutation profile of tumor specimen C3L-04362-05 (aliquot CPT0233810006) from CPTAC case C3L-04362, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.0 years (25,195 days).
Specimen C3L-04362-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 396cb378-ecac-4e8f-9c7f-4f4bdecfa2a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04362-32 (Blood Derived Normal), aliquot CPT0233870002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a517be3-eaf4-404c-9e35-5e4aad83a964

The open-access MAF lists 83 somatic variants for this specimen: 43 protein-altering or splice-affecting, 31 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 31, Frame Shift Del 4, RNA 4, Intron 3, Nonsense Mutation 3, In Frame Del 1, Splice Region 1, 3'UTR 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK5RAP2 | c.4672C>T p.R1558* | Nonsense Mutation (SNP) | VAF 208/482 reads (43%) | catalogued as rs373278668; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 132/148 reads (89%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCG4 | c.1916G>A p.R639H | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs746685392, COSV56642005, COSV56643302; called by muse, mutect2, varscan2
- ADAMTSL5 | c.1345G>A p.G449S | Missense Mutation (SNP) | VAF 115/349 reads (33%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.75); catalogued as rs747820135; called by muse, mutect2, varscan2
- ALMS1 | c.2536G>A p.G846R | Missense Mutation (SNP) | VAF 74/143 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs201154998; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASB10 | c.446G>A p.R149H (on ENST00000420175 / NM_001142459.2; = p.R134H on NM_080871.4) | Missense Mutation (SNP) | VAF 242/795 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as rs767142527, COSV51994400; called by muse, mutect2, varscan2
- CD5L | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1038401884, COSV63823188; called by muse, mutect2, varscan2
- CEP170B | c.835C>T p.P279S (on ENST00000453495; = p.P208S on NM_015005.3) | Missense Mutation (SNP) | VAF 181/433 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1281068342; called by muse, mutect2, varscan2
- COL6A6 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 75/195 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371005676; called by muse, mutect2, varscan2
- CRCT1 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 9/93 reads (10%) | PolyPhen benign (0.001); catalogued as rs1039931306; called by muse, mutect2
- DUOX2 | c.4465C>T p.H1489Y | Missense Mutation (SNP) | VAF 135/309 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66532242; called by muse, mutect2, varscan2
- GRIN2B | c.3388C>T p.R1130W | Missense Mutation (SNP) | VAF 116/249 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1320154351, COSV101663001; called by muse, mutect2, varscan2
- LPA | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 93/2868 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs760705738; called by muse, mutect2
- MELTF | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 193/423 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); catalogued as rs775456204, COSV99586736; called by muse, mutect2, varscan2
- MYH11 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 170/393 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.097); catalogued as rs1222746393, COSV55542343, COSV55573379; called by muse, mutect2, varscan2
- NLRP8 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 88/327 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs149738419; called by muse, mutect2, varscan2
- PDGFRA | c.2525_2527del p.D842_I843delinsV | In Frame Del (DEL) | VAF 157/420 reads (37%) | catalogued as COSV57271591; called by mutect2, pindel, varscan2
- PRELP | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 104/232 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1181590892, COSV100557852; called by muse, mutect2, varscan2
- PROKR2 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 124/398 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs1235576605, CM163185; called by muse, mutect2, varscan2
- PRR14L | c.2743_2744del p.V915Ifs*3 | Frame Shift Del (DEL) | VAF 39/107 reads (36%) | catalogued as rs769534246; called by mutect2, pindel, varscan2
- PSG4 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 105/406 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs370537366, COSV54933965, COSV54936173; called by muse, mutect2, varscan2
- PTH2R | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs559527804; called by muse, mutect2, varscan2
- TMEM255B | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 113/284 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs771068834, COSV64703540, COSV64704708; called by muse, mutect2, varscan2
- ZNF676 | c.896C>T p.T299I (on ENST00000650058; = p.T267I on NM_001001411.3) | Missense Mutation (SNP) | VAF 71/272 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.036); catalogued as rs11671566; called by muse, varscan2
- AR | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 185/388 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- ATXN2L | c.2950C>A p.H984N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- AXIN2 | c.1515del p.F505Lfs*2 | Frame Shift Del (DEL) | VAF 152/449 reads (34%) | called by mutect2, pindel, varscan2
- DROSHA | c.176del p.P59Lfs*49 | Frame Shift Del (DEL) | VAF 31/92 reads (34%) | called by mutect2, pindel, varscan2
- ENPEP | c.225G>T p.Q75H | Missense Mutation (SNP) | VAF 88/209 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- F8 | c.5377A>G p.T1793A | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KANK3 | c.1702G>A p.G568R | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- KTN1 | c.1963C>G p.Q655E | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- MAP3K10 | c.2461G>A p.V821M | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MYO1H | c.2260C>T p.Q754* | Nonsense Mutation (SNP) | VAF 139/325 reads (43%) | called by muse, mutect2, varscan2
- NEURL1 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 157/334 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOBOX | c.504C>A p.H168Q | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); called by muse, varscan2
- NPRL2 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 45/50 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP93 | c.1738T>G p.F580V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- PGAP6 | c.636G>A p.K212= | Splice Region (SNP) | VAF 137/318 reads (43%) | called by muse, mutect2, varscan2
- RHPN1 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SCN9A | c.1222C>A p.Q408K | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TXNIP | c.551_561del p.I184Rfs*4 | Frame Shift Del (DEL) | VAF 35/107 reads (33%) | called by mutect2, pindel, varscan2
- USP9X | c.3977+4_3977+7del p.X1326_splice | Splice Site (DEL) | VAF 16/59 reads (27%) | called by pindel, varscan2
- ADGRG7 | c.2340G>A p.P780= | Silent (SNP) | VAF 90/208 reads (43%) | catalogued as rs576939356; called by muse, mutect2, varscan2
- ADGRV1 | c.408A>G p.T136= | Silent (SNP) | VAF 15/48 reads (31%) | called by muse, varscan2
- ATP1B1 | c.516C>A p.G172= | Silent (SNP) | VAF 76/217 reads (35%) | catalogued as rs377019756; called by muse, mutect2, varscan2
- BTK | c.6C>T p.A2= | Silent (SNP) | VAF 84/237 reads (35%) | catalogued as rs372818780, COSV58117209, COSV58118150; called by muse, mutect2, varscan2
- CNTNAP2 | c.309G>A p.R103= | Silent (SNP) | VAF 129/463 reads (28%) | called by muse, mutect2, varscan2
- DNAI1 | c.1710C>T p.H570= | Silent (SNP) | VAF 123/268 reads (46%) | catalogued as rs746472041; called by muse, mutect2, varscan2
- DSP | c.687C>T p.G229= | Silent (SNP) | VAF 312/659 reads (47%) | catalogued as rs112877191; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GTF2F2 | c.681G>T p.G227= | Silent (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
- HECTD3 | c.114A>C p.A38= | Silent (SNP) | VAF 63/149 reads (42%) | called by muse, mutect2, varscan2
- HEPH | c.2953C>A p.R985= (on ENST00000343002; = p.R718= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 71/173 reads (41%) | called by muse, mutect2, varscan2
- JARID2 | c.690G>A p.R230= | Silent (SNP) | VAF 112/213 reads (53%) | called by muse, mutect2, varscan2
- KPNA7 | c.810C>T p.D270= | Silent (SNP) | VAF 215/753 reads (29%) | catalogued as rs369700638; ClinVar: likely benign; called by muse, mutect2, varscan2
- LAMA1 | c.1827C>T p.D609= | Silent (SNP) | VAF 125/302 reads (41%) | catalogued as rs1366414167, COSV67535858; called by muse, mutect2, varscan2
- LIMS2 | c.24C>T p.D8= (on ENST00000355119 / NM_001161403.3; = p.D32= on NM_017980.4) | Silent (SNP) | VAF 48/97 reads (49%) | catalogued as rs755783718; called by muse, mutect2, varscan2
- LRRC55 | c.786G>A p.A262= | Silent (SNP) | VAF 86/230 reads (37%) | catalogued as rs753677590, COSV73006908; called by muse, mutect2
- LRRN4 | c.678C>T p.D226= | Silent (SNP) | VAF 121/410 reads (30%) | called by muse, mutect2, varscan2
- LTB4R | c.291C>T p.C97= | Silent (SNP) | VAF 124/328 reads (38%) | catalogued as rs1176886230; called by muse, mutect2, varscan2
- MAP3K10 | c.936G>A p.A312= | Silent (SNP) | VAF 80/323 reads (25%) | catalogued as rs748129608; called by muse, mutect2, varscan2
- MYH7B | c.5643C>T p.H1881= | Silent (SNP) | VAF 93/280 reads (33%) | catalogued as rs755337363; called by muse, mutect2, varscan2
- NANOS3 | c.234C>T p.D78= (on ENST00000397555; = p.D97= on NM_001098622.2) | Silent (SNP) | VAF 133/448 reads (30%) | catalogued as rs371372685, COSV59248322; called by muse, mutect2, varscan2
- OR4C3 | c.156G>A p.T52= | Silent (SNP) | VAF 87/212 reads (41%) | catalogued as rs73463990; called by muse, mutect2, varscan2
- PLCZ1 | c.1767C>T p.S589= | Silent (SNP) | VAF 82/176 reads (47%) | called by muse, mutect2, varscan2
- PLXNA3 | c.4392C>T p.S1464= | Silent (SNP) | VAF 115/315 reads (37%) | catalogued as rs781978597; called by muse, mutect2, varscan2
- POLA1 | c.2904C>T p.Y968= | Silent (SNP) | VAF 63/177 reads (36%) | catalogued as rs1301073134, COSV66883268; called by muse, mutect2, varscan2
- POTEB3 | c.369C>T p.Y123= | Silent (SNP) | VAF 59/224 reads (26%) | catalogued as rs1233556920; called by mutect2, varscan2
- TEX13B | c.759T>A p.L253= | Silent (SNP) | VAF 261/570 reads (46%) | called by muse, mutect2, varscan2
- THBS4 | c.249C>T p.N83= | Silent (SNP) | VAF 144/319 reads (45%) | catalogued as rs1264574041; called by muse, mutect2, varscan2
- TNFRSF11A | c.1767G>A p.P589= | Silent (SNP) | VAF 85/182 reads (47%) | catalogued as rs1294659238; called by muse, mutect2, varscan2
- TRIML2 | c.1062C>A p.V354= | Silent (SNP) | VAF 55/108 reads (51%) | called by muse, mutect2, varscan2
- TSPAN10 | c.429G>A p.K143= (on ENST00000574882 / NM_001290212.1; = p.K105= on NM_031945.4) | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1424640914; called by muse, mutect2, varscan2
- TSPO2 | c.348G>C p.L116= | Silent (SNP) | VAF 166/356 reads (47%) | called by muse, mutect2, varscan2
- AC011525.1 | n.903G>A | RNA (SNP) | VAF 76/212 reads (36%) | catalogued as rs547088716; called by muse, mutect2, varscan2
- AGAP14P | n.45C>T | RNA (SNP) | VAF 75/464 reads (16%) | called by mutect2, varscan2
- FA2H | c.*4C>T | 3'UTR (SNP) | VAF 71/146 reads (49%) | called by muse, varscan2
- FXYD6-FXYD2 | c.259+6038C>A | Intron (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- PLCH2 | c.2959+17G>A | Intron (SNP) | VAF 214/253 reads (85%) | catalogued as rs539454703, COSV53950717; called by muse, mutect2, varscan2
- QKI | c.1010-1226C>T | Intron (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- SLC25A5 | chrX:119468379 G>A | 5'Flank (SNP) | VAF 98/214 reads (46%) | called by muse, mutect2, varscan2
- SNORD115-1 | n.32_33del | RNA (DEL) | VAF 135/396 reads (34%) | called by mutect2, pindel, varscan2
- UGT2B27P | n.938G>A | RNA (SNP) | VAF 96/220 reads (44%) | catalogued as rs1391675466; called by muse, mutect2, varscan2
